Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4982, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4982-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

TCGA - BP - 4982

Clinical Diagnosis & History:

with 5 cm mass identified on work-up for flank pain.

Specimens Submitted:

1: SP: Kidney, left, partial nephrectomy

DIAGNOSIS:

1. SP: Kidney, left, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 4.5 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Interstitial fibrosis and chronic inflammation, tubular atrophy

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1) The specimen is received fresh for frozen sections consultation labeled "Left kidney tumor, stitch marks deep margin". It consists of a 6 x 5 x 4 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black, the rest is inked in blue and the specimen is serially sectioned to reveal a golden yellow poorly circumscribed with focally hemorrhagic and gelatinous areas. The tumor measures 4.5 x 4 x 3.7 cm. The clearance from the resection margin is 1 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS. No lymph nodes is identified on the perinephric adipose tissue. The specimen is photographed.

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

RS - representative sections

Summary of Sections:

Part 1: SP: Kidney, left, partial nephrectomy

Block	Sect. Site	PCs
1	FSC	1
1	M	1
5	RS	5
2	T	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM; ENCAPSULATED. THE DESIGNATED DEEP MARGIN IS NEGATIVE (<1 MM).
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file f8939fda-2fbb-4a79-bce2-eb47b8b85f91 (TCGA-BP-4982.9B725CC0-38F5-4DD1-9CF9-EE3DE8B66F8C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).